Somatic mutation profile of tumor specimen MMRF_1857_1_BM_CD138pos (aliquot MMRF_1857_1_BM_CD138pos_T1_KBS5U_L05779) from MMRF case MMRF_1857, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.3 years (26,054 days).
Specimen MMRF_1857_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bcf267d-b351-4a06-b779-b57aa2cae745.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1857_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1857_1_PB_Whole_C3_KBS5U_L05805; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f8b9e22-d4db-46e2-ab99-66a101b413e4

The open-access MAF lists 84 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 14, Silent 13, Intron 9, Nonsense Mutation 4, 5'UTR 3, 5'Flank 3, 3'Flank 3, Frame Shift Ins 2, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F13A1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 62/153 reads (41%) | catalogued as rs121913065, CM930201, COSV53553799, COSV53554927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCAM | c.1028A>G p.D343G | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV54300638; called by muse, mutect2, varscan2
- CALML5 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV66702471; called by muse, mutect2, varscan2
- CLASRP | c.1264_1275del p.W422_S425del | In Frame Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs772522748; called by mutect2, varscan2
- CYP27C1 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as rs373145563; called by muse, mutect2, varscan2
- FAT2 | c.7384C>T p.R2462* | Nonsense Mutation (SNP) | VAF 30/116 reads (26%) | catalogued as rs199842636, COSV55819596; called by muse, mutect2, varscan2
- H1-3 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs147157401, COSV55097409; called by muse, mutect2
- IGHV2-70 | c.220dup p.W74Lfs*3 | Frame Shift Ins (INS) | VAF 24/48 reads (50%) | catalogued as rs748161456; called by pindel, varscan2
- IGHV2-70 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs374599053; called by muse, varscan2
- IGHV2-70 | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs372640551; called by muse, varscan2
- IGHV2-70 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs369724963; called by muse, varscan2
- IGHV2-70 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs552206369; called by muse, varscan2
- IGHV2-70 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs549341348; called by muse, varscan2
- IGKV4-1 | c.358A>T p.T120S | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs192141151; called by muse, varscan2
- IGLL5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as rs538723125, COSV73251010, COSV73251135, COSV73251305; called by muse, mutect2, varscan2
- IGLV3-1 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs61736464; called by muse, varscan2
- IGLV3-1 | c.148T>G p.Y50D | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs368495152; called by muse, varscan2
- IGLV3-1 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs181381534; called by muse, varscan2
- KHDRBS3 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 123/246 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as rs138429826; called by muse, mutect2, varscan2
- MLXIP | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs772995790, COSV59833926, COSV59834108; called by muse, mutect2, varscan2
- MLXIPL | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as rs1554603178; called by muse, mutect2
- OR4C13 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV73648683; called by muse, mutect2, varscan2
- SIAH2 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs760253969; called by muse, varscan2
- SLC15A1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs548069102; called by muse, mutect2, varscan2
- TLE6 | c.481G>A p.E161K (on ENST00000246112 / NM_001143986.2; = p.E38K on NM_024760.3) | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs906514054; called by muse, mutect2, varscan2
- ZCCHC4 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV57180920; called by muse, mutect2, varscan2
- AL031777.2 | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 95/198 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFH | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CSK | c.689C>G p.A230G | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); called by muse, mutect2
- HECTD4 | c.3374G>C p.G1125A | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- IGHV2-70D | c.101C>G p.T34R | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, varscan2
- JAG2 | c.2610A>T p.R870S | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- LOXHD1 | c.635dup p.D213Gfs*4 | Frame Shift Ins (INS) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- MTNR1A | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- RABL6 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCN9A | c.1314G>A p.E438= | Splice Region (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- UROC1 | c.1039C>G p.H347D | Missense Mutation (SNP) | VAF 84/132 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF737 | c.1543G>T p.G515C | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CSMD1 | c.8637C>T p.G2879= (on ENST00000520002; = p.G2878= on NM_033225.6) | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs776260093, COSV100146615, COSV59332793; called by muse, mutect2, varscan2
- IGHV2-70 | c.228T>C p.D76= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs373802343; called by muse, varscan2
- IGHV2-70D | c.237C>T p.F79= | Silent (SNP) | VAF 35/38 reads (92%) | called by muse, varscan2
- IGHV2-70D | c.57C>T p.S19= | Silent (SNP) | VAF 34/36 reads (94%) | called by muse, varscan2
- IGLV3-1 | c.243T>C p.S81= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as rs368837026; called by muse, varscan2
- IGLV3-1 | c.345C>T p.H115= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs778942547; called by muse, varscan2
- MLIP | c.801C>T p.T267= | Silent (SNP) | VAF 63/134 reads (47%) | called by muse, mutect2, varscan2
- NOS1 | c.1455C>A p.I485= | Silent (SNP) | VAF 52/86 reads (60%) | called by muse, mutect2, varscan2
- PHLDB2 | c.2613C>T p.S871= (on ENST00000393925 / NM_001134439.2; = p.S828= on NM_145753.2) | Silent (SNP) | VAF 3/52 reads (6%) | catalogued as rs1158113520, COSV67307488; called by muse, mutect2
- RCVRN | c.168C>T p.F56= | Silent (SNP) | VAF 48/136 reads (35%) | called by muse, mutect2, varscan2
- SIAH2 | c.33T>C p.A11= | Silent (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- TM7SF3 | c.351A>C p.I117= | Silent (SNP) | VAF 77/173 reads (45%) | called by muse, mutect2, varscan2
- TUB | c.642T>C p.N214= (on ENST00000299506 / NM_177972.3; = p.N269= on NM_003320.4) | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs756662823, COSV55108854; called by muse, mutect2, varscan2
- ACTB | c.-27-121G>T | Intron (SNP) | VAF 30/104 reads (29%) | catalogued as rs533676634, COSV59317189; called by muse, varscan2
- ACTB | c.-27-265G>C | Intron (SNP) | VAF 10/14 reads (71%) | catalogued as rs996454997; called by muse, varscan2
- ALDH7A1 | c.*2065G>A | 3'UTR (SNP) | VAF 38/122 reads (31%) | catalogued as rs918487766; called by muse, mutect2, varscan2
- ARHGEF7 | c.*1261G>A | 3'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ASCC3 | c.241+5163G>A | Intron (SNP) | VAF 65/111 reads (59%) | catalogued as rs1378273557; called by muse, mutect2, varscan2
- BROX | c.-362T>C | 5'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- C7orf57 | c.*189T>A | 3'UTR (SNP) | VAF 33/55 reads (60%) | called by muse, mutect2, varscan2
- CRYAB | c.325-239G>A | Intron (SNP) | VAF 36/149 reads (24%) | catalogued as rs1280958718; called by muse, mutect2, varscan2
- ERLIN2 | c.*2467T>G | 3'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- FARP1 | c.*550T>C | 3'UTR (SNP) | VAF 26/54 reads (48%) | catalogued as rs913050457; called by muse, mutect2, varscan2
- FHL2 | chr2:105399129 G>A | 5'Flank (SNP) | VAF 29/149 reads (19%) | called by muse, mutect2, varscan2
- HNRNPH3 | c.640-45T>C | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- HP1BP3 | c.*43T>A | 3'UTR (SNP) | VAF 83/185 reads (45%) | called by muse, mutect2, varscan2
- IGHEP1 | n.561G>C | RNA (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- IGLL5 | c.-91A>G | 5'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- IL1RL2 | c.*440C>T | 3'UTR (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- KIRREL3 | c.55+5105T>C | Intron (SNP) | VAF 11/388 reads (3%) | catalogued as rs1198873014; called by muse, mutect2
- LTB | c.162+136G>A | Intron (SNP) | VAF 23/48 reads (48%) | catalogued as rs541787102; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851168 T>C | 5'Flank (SNP) | VAF 68/131 reads (52%) | catalogued as rs186707620; called by muse, varscan2
- NAA25 | c.*164T>C | 3'UTR (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-634A>G | Intron (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- RUFY3 | chr4:70793802 G>A | 3'Flank (SNP) | VAF 10/26 reads (38%) | catalogued as rs773563007; called by muse, mutect2, varscan2
- SAMD12 | c.*1171T>C | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- SEMA3D | c.*166A>T | 3'UTR (SNP) | VAF 48/78 reads (62%) | called by muse, mutect2, varscan2
- SEMA4D | chr9:89376946 G>A | 3'Flank (SNP) | VAF 53/103 reads (51%) | catalogued as rs762670816; called by muse, mutect2, varscan2
- SLC7A11 | c.*4790A>C | 3'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, varscan2
- SRD5A3 | c.*567C>T | 3'UTR (SNP) | VAF 8/19 reads (42%) | catalogued as rs1280090007; called by muse, mutect2, varscan2
- SYCE1 | chr10:133553927 del T | 3'Flank (DEL) | VAF 21/58 reads (36%) | catalogued as rs79413613; called by mutect2, varscan2
- TCEANC2 | c.*2005A>C | 3'UTR (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2, varscan2
- TMEM41A | c.*1760G>A | 3'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975304 G>C | 5'Flank (SNP) | VAF 76/78 reads (97%) | catalogued as COSV66081281; called by muse, mutect2, varscan2
- ZNF317 | c.-140G>A | 5'UTR (SNP) | VAF 12/255 reads (5%) | catalogued as rs1240600382; called by muse, mutect2
- ZNF598 | c.466-92C>T | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
